TCGA case TCGA-DX-A3U7 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ea3a524b-6ee3-4904-8924-29fcaa20985c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Dead; Days to death: 1,552 days (4.2 years).

Diagnoses (9)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 67.7 years (24,723 days); Year of diagnosis: 2009; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6.3; Tumor length measurement: 9.2; Tumor width measurement: 7.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Tumor depth descriptor: Superficial.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 6.2; Tumor length measurement: 8.8; Tumor width measurement: 7.3.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 68.6 years (25,072 days); Days to diagnosis: 349 days; Prior treatment: Yes; Tumor focality: Multifocal.
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Liver. Age at diagnosis: 68.6 years (25,072 days); Days to diagnosis: 349 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2.2; Tumor length measurement: 3.5; Tumor width measurement: 2.6.
4. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 69.3 years (25,328 days); Days to diagnosis: 605 days (1.7 years); Prior treatment: Yes; Tumor focality: Multifocal.
5. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Liver. Age at diagnosis: 69.7 years (25,463 days); Days to diagnosis: 740 days (2.0 years); Prior treatment: Yes.
6. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Peritoneum, NOS. Age at diagnosis: 70.5 years (25,754 days); Days to diagnosis: 1,031 days (2.8 years); Prior treatment: Yes.
7. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Kidney, NOS. Age at diagnosis: 70.5 years (25,754 days); Days to diagnosis: 1,031 days (2.8 years); Prior treatment: Yes.
8. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Pelvic bones, sacrum, coccyx and associated joints. Age at diagnosis: 71.2 years (26,007 days); Days to diagnosis: 1,284 days (3.5 years); Prior treatment: Yes.
9. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Bone, NOS. Age at diagnosis: 71.2 years (26,007 days); Days to diagnosis: 1,284 days (3.5 years); Prior treatment: Yes.

Follow-up (10 entries)
- Day 349 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 349 days.
- Day 349 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 349 days.
- Day 605 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 605 days (1.7 years).
- Day 740 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 740 days (2.0 years).
- Day 1,031 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Peritoneum, NOS; Days to progression: 1,031 days (2.8 years).
- Day 1,031 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Kidney, NOS; Days to progression: 1,031 days (2.8 years).
- Day 1,284 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 1,284 days (3.5 years).
- Day 1,284 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pelvic bones, sacrum, coccyx and associated joints; Days to progression: 1,284 days (3.5 years).
- Days to follow up: 1,301 days (3.6 years); Disease response: With Tumor.
- Days to follow up: 1,552 days (4.2 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A3U7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-DX-A3U7-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 88; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A3U7-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A3U7-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Disease multifocal indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 350; Days from index date to pharmaceutical treatment ended: 549; Pharmaceutical therapy drug name: Taxotere; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 350; Days from index date to pharmaceutical treatment ended: 606; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 741; Days from index date to pharmaceutical treatment ended: 922; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.
- Drug treatment 4: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 741; Days from index date to pharmaceutical treatment ended: 922; Pharmaceutical therapy drug name: Taxotere; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 942; Days from index date to pharmaceutical treatment ended: 945; Pharmaceutical therapy drug name: Doxorubicin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 6: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 969; Days from index date to pharmaceutical treatment ended: 1126; Pharmaceutical therapy drug name: Doxil; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 7: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 1133; Days from index date to pharmaceutical treatment ended: 1182; Pharmaceutical therapy drug name: Pazopanib; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 8: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 1258; Pharmaceutical therapy drug name: Dacarbazine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 9: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 1352; Days from index date to pharmaceutical treatment ended: 1427; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Days from index date to radiation therapy started: 1312; Days from index date to radiation therapy ended: 1323; Radiation therapy type: External; Radiation total dose: 3000; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 10; Radiation therapy site: Distant Recurrence; Radiation therapy ongoing indicator: No; Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,552 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,552 days; disease-free interval: event (new tumor event after initially disease-free), 349 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 349 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A3U7-01A-11D-A29M-01): tumor purity 0.86, ploidy 3.21, whole-genome doublings 1.
